Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3316, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3316-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time: [REDACTED]

Surgical Pathology

Histopathological Examination [REDACTED]

Path#: [REDACTED]
Collected: [REDACTED] Received: [REDACTED] Complete: [REDACTED]

Pre-Op Diagnosis: [REDACTED]
Order Physician: [REDACTED]
Specimens: Kidney, Left
Frozen Diagnosis: [REDACTED]

Report : GROSS EXAMINATION.
The specimen is received in a container labeled with the name of the patient and labeled as kidney, left. The specimen consists of a kidney and attached perinephric fat which measures en bloc 15 x 12 x 7.5 cm and weighs 605 g. The ureter and vascular margins of resection are submitted in block 1. The mid and lower portion of the kidney shows a large golden yellow and brown mass measuring 9.0 x 8.5 x 7.0 cm. The mass grossly extends through the capsule to within approximately 0.2 cm of the inked surgical margin. Sections of the inked soft tissue margins are submitted in blocks 2-3. The mass grossly bulges against the renal vein and renal pelvis but does not extend into either grossly. Sections of the mass and adjacent renal vein are submitted in blocks 4-5. A section of the mass and the adjacent pelvis is submitted in block 6. Additional sections of the mass are submitted in blocks 7-10. The pelvis and calices are not grossly dilated. The cortex averages 0.5 cm. A random section of kidney is submitted in block 11. Sectioning through the attached fat shows a portion of adrenal gland measuring 2.5 cm. Representative sections are submitted in block 12. [REDACTED]

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

SPECIMEN TYPE: Radical nephrectomy
LATERALITY: Left
TUMOR SITE: Middle and lower poles
FOCALITY: Unifocal
TUMOR SIZE:
Greatest dimension: 9.0 cm
Additional dimensions: 8.5 x 7.0 cm
MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney
HISTOLOGIC TYPE: Clear cell (conventional) renal cell

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS [REDACTED]

Path #: [REDACTED]
Visit #: [REDACTED]

[page 2 of 2]
carcinoma

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): Grade 3: Nuclei very irregular, approximately 20 microns; nucleoli large and prominent.

EXTENT OF INVASION

PRIMARY TUMOR (PT): pT2: Tumor more than 7 cm in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES (PN): pNX: Cannot be assessed

DISTANT METASTASIS (PM): pMX: Cannot be assessed

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Present and uninvolved by tumor

VENOUS (LARGE VESSEL) INVASION (V): Absent

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: None identified.

PATHOLOGIC STAGE: pT2NXMX

[T-71000 M-83103 189.0 P3-44070]

Intradepartmental consultation obtained.

Electronically Signed by:

Source: NCI Genomic Data Commons file 7f984691-8f0e-4bd7-bdfe-498b936a7be5 (TCGA-A3-3316.2A017148-457B-4251-9F41-7F05C4B70025.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).